Somatic mutation profile of tumor specimen 0DFBLP from CCDI case PBBPMR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 2.6 years (942 days).
Specimen 0DFBLP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 578d2df1-cbfa-406a-bab9-0d8166874bf6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFBLB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d22d48b-f29d-4478-88ca-28d4a7f8b48a

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 6, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 84/384 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS13 | c.3170C>T p.A1057V | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.231); catalogued as rs1056233134, COSV63023009; called by muse, mutect2, varscan2
- ATXN1 | c.2101G>A p.V701M | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1395417495, COSV99786655; called by muse, mutect2
- DPEP1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs750576563, COSV55360769; called by muse, mutect2, varscan2
- HECW1 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs770350541; called by muse, mutect2, varscan2
- MYH6 | c.2481G>T p.K827N | Missense Mutation (SNP) | VAF 96/389 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62449989, COSV62454840; called by muse, mutect2, varscan2
- PEG3 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 57/316 reads (18%) | catalogued as COSV55631724; called by muse, mutect2, varscan2
- QPRT | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.755); catalogued as rs745444576, COSV54880292; called by muse, mutect2, varscan2
- SLC15A2 | c.796C>A p.R266S | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55201581; called by muse, mutect2, varscan2
- TNR | c.1291G>A p.V431M | Missense Mutation (SNP) | VAF 50/474 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs778097851, COSV54906440; called by muse, mutect2, varscan2
- P4HB | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ROBO2 | c.36G>T p.M12I | Missense Mutation (SNP) | VAF 108/355 reads (30%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHROOM3 | c.73T>C p.Y25H | Missense Mutation (SNP) | VAF 70/339 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- KCNJ16 | c.327A>G p.T109= | Silent (SNP) | VAF 95/255 reads (37%) | called by muse, mutect2, varscan2
- NAV2 | c.5793G>A p.Q1931= (on ENST00000396087 / NM_001244963.2; = p.Q1872= on NM_145117.5) | Silent (SNP) | VAF 87/351 reads (25%) | catalogued as rs1157102649; called by muse, mutect2, varscan2
- TFR2 | c.1242C>T p.F414= | Silent (SNP) | VAF 153/342 reads (45%) | catalogued as rs150883560; called by muse, mutect2, varscan2
- TMPRSS15 | c.1620G>T p.T540= | Silent (SNP) | VAF 61/284 reads (21%) | catalogued as COSV53043333; called by muse, mutect2, varscan2
- ANKDD1A | c.768+67C>T | Intron (SNP) | VAF 8/39 reads (21%) | catalogued as rs754547145; called by muse, mutect2, varscan2
- ARHGAP44 | c.2317+33T>A | Intron (SNP) | VAF 43/187 reads (23%) | catalogued as rs770923834, COSV52394818; called by muse, mutect2, varscan2
- NDUFS7 | c.456-62C>T | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- TCIRG1 | c.504-12del | Intron (DEL) | VAF 20/76 reads (26%) | called by mutect2, varscan2
- TTN | c.38290+41C>A | Intron (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- ZNF587 | c.33+80C>T | Intron (SNP) | VAF 9/48 reads (19%) | catalogued as rs535023272; called by muse, mutect2, varscan2
